Somatic mutation profile of tumor specimen TARGET-20-PARUWX-09A (aliquot TARGET-20-PARUWX-09A-02D) from TARGET case TARGET-20-PARUWX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,049 days).
Specimen TARGET-20-PARUWX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f1d2d71-3470-4c0a-822b-d265ab68b310.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUWX-14A (Bone Marrow Normal), aliquot TARGET-20-PARUWX-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c87a6f8-4b20-4ea5-9559-8d6c6c976643

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF469 | c.2103G>T p.G701= | Silent (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
